Somatic mutation profile of tumor specimen ALCH-ADXS-TTP1-A (aliquot ALCH-ADXS-TTP1-A-1-0-D-A549-36) from ALCHEMIST case ALCH-ADXS, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Squamous cell carcinoma, NOS; Age at diagnosis: 75.9 years (27,713 days).
Specimen ALCH-ADXS-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) da0d2718-ecf4-4db4-94b4-ae61a6d2c5f8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-ADXS-NB1-A (Blood Derived Normal), aliquot ALCH-ADXS-NB1-A-1-0-D-A549-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ff6497e8-0a5b-45ee-a29a-2a7ea00ef05c

The open-access MAF lists 223 somatic variants for this specimen: 150 protein-altering or splice-affecting, 44 silent, 29 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 131, Silent 44, Intron 14, Nonsense Mutation 6, Splice Site 6, 3'UTR 5, RNA 5, Frame Shift Del 4, 5'UTR 3, Frame Shift Ins 2, 5'Flank 2, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FGF10 | c.467T>G p.I156R | Missense Mutation (SNP) | VAF 76/819 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs104893886, CM060990; ClinVar: pathogenic; called by muse, mutect2
- KEAP1 | c.959G>A p.R320Q | Missense Mutation (SNP) | VAF 29/192 reads (15%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.889); catalogued as COSV50260372, COSV50272556, COSV50274400; called by muse, mutect2, varscan2
- TP53 | c.388C>G p.L130V | Missense Mutation (SNP) | VAF 47/344 reads (14%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs863224683, CM016206, COSV52686543, COSV52692226, COSV99368721; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ABCA4 | c.2742C>A p.H914Q | Missense Mutation (SNP) | VAF 122/820 reads (15%) | SIFT tolerated (0.7); PolyPhen benign (0); catalogued as COSV100933181; called by muse, mutect2, varscan2
- ABCG4 | c.1210G>A p.V404M | Missense Mutation (SNP) | VAF 92/496 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.954); catalogued as rs376407071, COSV56645115; called by muse, mutect2, varscan2
- ANKRD60 | c.343G>T p.D115Y | Missense Mutation (SNP) | VAF 152/511 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); catalogued as rs921811420; called by muse, mutect2, varscan2
- ANXA6 | c.1597G>A p.A533T | Missense Mutation (SNP) | VAF 110/484 reads (23%) | SIFT tolerated (0.28); PolyPhen benign (0.127); catalogued as rs774231228; called by muse, mutect2, varscan2
- BAHCC1 | c.2602C>T p.Q868* | Nonsense Mutation (SNP) | VAF 72/245 reads (29%) | catalogued as COSV57025003; called by muse, mutect2, varscan2
- BEND2 | c.1338C>G p.N446K | Missense Mutation (SNP) | VAF 45/192 reads (23%) | SIFT tolerated (0.13); PolyPhen benign (0.019); catalogued as COSV66215989; called by muse, mutect2, varscan2
- C12orf60 | c.577del p.D193Mfs*3 | Frame Shift Del (DEL) | VAF 48/193 reads (25%) | catalogued as COSV57451963; called by mutect2, pindel, varscan2
- C2CD2L | c.483del p.R162Gfs*6 | Frame Shift Del (DEL) | VAF 30/286 reads (10%) | catalogued as COSV100371470; called by mutect2, pindel, varscan2
- C4orf54 | c.2713G>T p.E905* | Nonsense Mutation (SNP) | VAF 58/282 reads (21%) | catalogued as COSV104440103; called by muse, mutect2, varscan2
- CD3E | c.614G>A p.R205K | Missense Mutation (SNP) | VAF 111/765 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs780379117; called by muse, mutect2, varscan2
- CDH10 | c.124C>T p.P42S | Missense Mutation (SNP) | VAF 44/464 reads (9%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as COSV52574935; called by muse, mutect2
- CDH18 | c.1124G>T p.G375V | Missense Mutation (SNP) | VAF 34/589 reads (6%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.67); catalogued as COSV56966683; called by muse, mutect2
- CELSR2 | c.3919G>A p.E1307K | Missense Mutation (SNP) | VAF 26/148 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV54768304; called by muse, mutect2, varscan2
- COL4A2 | c.477+1G>T p.X159_splice | Splice Site (SNP) | VAF 14/135 reads (10%) | catalogued as COSV64624880; called by muse, mutect2
- CSMD3 | c.9389G>T p.G3130V (on ENST00000297405 / NM_001363185.1; = p.G2961V on NM_052900.3) | Missense Mutation (SNP) | VAF 22/212 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); catalogued as COSV52312837; called by muse, mutect2
- CYP2A6 | c.1382G>A p.R461H | Missense Mutation (SNP) | VAF 54/530 reads (10%) | SIFT tolerated (0.16); PolyPhen benign (0.007); catalogued as rs764629023, COSV56534212; called by muse, mutect2
- DOC2A | c.760C>T p.R254C | Missense Mutation (SNP) | VAF 49/254 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs779856487; called by muse, mutect2, varscan2
- GALNT13 | c.575G>T p.R192L | Missense Mutation (SNP) | VAF 55/434 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV67227982; called by muse, mutect2, varscan2
- GRIK1 | c.780+1G>A p.X260_splice | Splice Site (SNP) | VAF 55/414 reads (13%) | catalogued as rs1314822532; called by muse, mutect2, varscan2
- HAVCR1 | c.563C>A p.T188K | Missense Mutation (SNP) | VAF 124/1088 reads (11%) | SIFT tolerated (0.12); PolyPhen benign (0.012); catalogued as COSV100208124; called by muse, mutect2, varscan2
- HHATL | c.398C>T p.S133L | Missense Mutation (SNP) | VAF 27/178 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.45); catalogued as rs769163062; called by muse, mutect2, varscan2
- HK3 | c.277G>A p.V93M | Missense Mutation (SNP) | VAF 94/598 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as rs761051620; called by muse, mutect2, varscan2
- ITGA8 | c.2087C>T p.A696V | Missense Mutation (SNP) | VAF 24/166 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV65228008; called by muse, mutect2, varscan2
- KIF17 | c.1786C>A p.L596I | Missense Mutation (SNP) | VAF 35/254 reads (14%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0); catalogued as rs138626725; called by muse, mutect2, varscan2
- KMT2D | c.15641G>T p.R5214L | Missense Mutation (SNP) | VAF 79/267 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs398123729, CM105480, COSV56427001, COSV99977974; called by muse, mutect2, varscan2
- MROH2A | c.1142G>A p.R381H | Missense Mutation (SNP) | VAF 28/177 reads (16%) | SIFT tolerated (0.78); PolyPhen benign (0.11); catalogued as rs557519740; called by muse, mutect2, varscan2
- MUC16 | c.4178C>A p.S1393Y | Missense Mutation (SNP) | VAF 55/358 reads (15%) | SIFT tolerated, low confidence (0.08); PolyPhen possibly damaging (0.457); catalogued as rs771602252; called by muse, mutect2, varscan2
- NBEA | c.8231G>C p.R2744P | Missense Mutation (SNP) | VAF 42/494 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.955); catalogued as COSV59763177; called by muse, mutect2
- NOX4 | c.713C>T p.S238F | Missense Mutation (SNP) | VAF 27/187 reads (14%) | SIFT tolerated (0.38); PolyPhen benign (0.005); catalogued as COSV54451535; called by muse, mutect2, varscan2
- NTNG2 | c.1318G>A p.D440N | Missense Mutation (SNP) | VAF 58/348 reads (17%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.663); catalogued as COSV62365449; called by muse, mutect2, varscan2
- OR10G4 | c.190C>A p.L64M | Missense Mutation (SNP) | VAF 67/488 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57978324; called by muse, mutect2, varscan2
- OR2G2 | c.232A>T p.S78C | Missense Mutation (SNP) | VAF 94/794 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.864); catalogued as COSV60741340; called by muse, mutect2, varscan2
- OR2T2 | c.899C>A p.A300E | Missense Mutation (SNP) | VAF 84/1358 reads (6%) | SIFT tolerated (0.23); PolyPhen benign (0.001); catalogued as COSV61617655; called by muse, mutect2
- OR6K3 | c.539C>A p.S180Y (on ENST00000368146; = p.S164Y on NM_001005327.2) | Missense Mutation (SNP) | VAF 75/627 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100933882; called by muse, mutect2, varscan2
- PCDH10 | c.887G>T p.R296L | Missense Mutation (SNP) | VAF 112/536 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.577); catalogued as COSV52093848; called by muse, mutect2, varscan2
- PCDHB14 | c.1345C>T p.P449S | Missense Mutation (SNP) | VAF 238/1400 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs782758026; called by muse, mutect2, varscan2
- PDGFD | c.901C>T p.R301C | Missense Mutation (SNP) | VAF 114/676 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs780198804, COSV56383688; called by muse, mutect2, varscan2
- PIEZO2 | c.2323G>C p.E775Q | Missense Mutation (SNP) | VAF 13/76 reads (17%) | SIFT tolerated (0.35); PolyPhen benign (0.028); catalogued as COSV100128281; called by muse, mutect2
- PITPNM3 | c.1942C>T p.P648S | Missense Mutation (SNP) | VAF 107/500 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.025); catalogued as rs141159316; ClinVar: likely benign; called by muse, mutect2, varscan2
- PLEC | c.8890G>T p.D2964Y (on ENST00000322810 / NM_201380.4; = p.D2854Y on NM_000445.5) | Missense Mutation (SNP) | VAF 76/471 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.248); catalogued as rs782526828, COSV59610796, COSV59657894; called by muse, mutect2, varscan2
- PRDM9 | c.355A>G p.M119V | Missense Mutation (SNP) | VAF 93/911 reads (10%) | SIFT tolerated, low confidence (0.43); PolyPhen benign (0.007); catalogued as rs761821081; called by muse, mutect2
- PRDM9 | c.885C>G p.I295M | Missense Mutation (SNP) | VAF 259/1594 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV57007968, COSV99690319; called by muse, mutect2, varscan2
- PREP | c.398G>A p.G133D (on ENST00000369110; = p.G199D on NM_002726.5) | Missense Mutation (SNP) | VAF 33/234 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100963834; called by muse, mutect2, varscan2
- PROKR2 | c.459-1G>T p.X153_splice | Splice Site (SNP) | VAF 38/318 reads (12%) | catalogued as COSV54085481; called by muse, mutect2
- PTDSS2 | c.784A>G p.M262V | Missense Mutation (SNP) | VAF 49/433 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.145); catalogued as rs760829647; called by muse, mutect2, varscan2
- REG1A | c.403G>T p.G135C | Missense Mutation (SNP) | VAF 28/366 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52069762; called by muse, mutect2
- RNASE10 | c.242C>T p.P81L | Missense Mutation (SNP) | VAF 28/280 reads (10%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as rs778528075; called by muse, mutect2
- RNF123 | c.2735G>A p.R912H | Missense Mutation (SNP) | VAF 42/318 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs548408209; called by muse, mutect2, varscan2
- SHROOM2 | c.1513G>A p.E505K | Missense Mutation (SNP) | VAF 40/120 reads (33%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as rs146916164, COSV66610539; called by muse, mutect2, varscan2
- SLC1A7 | c.1447C>T p.R483W | Missense Mutation (SNP) | VAF 71/534 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as rs781446041, COSV100439687; called by muse, mutect2, varscan2
- SPATA31E1 | c.1198A>G p.I400V | Missense Mutation (SNP) | VAF 17/473 reads (4%) | SIFT tolerated (0.77); PolyPhen benign (0.123); catalogued as rs1173756721, COSV100350977; called by muse, mutect2
- TAAR8 | c.665T>A p.I222K | Missense Mutation (SNP) | VAF 51/318 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.633); catalogued as rs745320870; called by muse, mutect2, varscan2
- TBC1D10A | c.85G>A p.G29S | Missense Mutation (SNP) | VAF 8/59 reads (14%) | SIFT tolerated (0.48); PolyPhen benign (0.001); catalogued as rs985439622; called by muse, mutect2, varscan2
- TCTN2 | c.1849G>A p.V617I | Missense Mutation (SNP) | VAF 266/956 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.982); catalogued as rs376095561; called by muse, mutect2, varscan2
- TERF2IP | c.421G>A p.D141N | Missense Mutation (SNP) | VAF 105/452 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as rs1483617225; called by muse, mutect2, varscan2
- TLCD5 | c.238C>G p.L80V (on ENST00000375095 / NM_001198671.2; = p.L102V on NM_174926.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 25/231 reads (11%) | SIFT tolerated (0.21); PolyPhen benign (0.099); catalogued as rs543156640; called by muse, mutect2
- TPO | c.2458G>T p.G820C | Missense Mutation (SNP) | VAF 119/966 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.94); catalogued as rs750948449; called by muse, mutect2, varscan2
- TRIM3 | c.823C>T p.R275* | Nonsense Mutation (SNP) | VAF 54/539 reads (10%) | catalogued as rs762184285; called by muse, mutect2
- TRIM67 | c.1816G>A p.D606N | Missense Mutation (SNP) | VAF 22/120 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.056); catalogued as rs372935882; called by muse, mutect2, varscan2
- TRPA1 | c.1627C>T p.R543C | Missense Mutation (SNP) | VAF 58/346 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); catalogued as rs746056010, COSV51557783; called by muse, mutect2, varscan2
- TRPV6 | c.1585G>C p.D529H | Missense Mutation (SNP) | VAF 31/606 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63891797; called by muse, mutect2
- TTN | c.3553C>A p.Q1185K (on ENST00000591111; = p.Q1139K on NM_003319.4) | Missense Mutation (SNP) | VAF 64/508 reads (13%) | PolyPhen benign (0.033); catalogued as COSV59880924; called by muse, mutect2, varscan2
- TXNL1 | c.19G>T p.V7F | Missense Mutation (SNP) | VAF 20/145 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.505); catalogued as rs779953668; called by muse, mutect2, varscan2
- A3GALT2 | c.784G>C p.V262L | Missense Mutation (SNP) | VAF 7/51 reads (14%) | SIFT tolerated (0.32); PolyPhen benign (0.384); called by muse, mutect2, varscan2
- ABCC9 | c.3118A>T p.S1040C | Missense Mutation (SNP) | VAF 44/434 reads (10%) | SIFT tolerated (0.1); PolyPhen benign (0.061); called by muse, mutect2, varscan2
- ARFGAP3 | c.1019dup p.Y341Vfs*2 | Frame Shift Ins (INS) | VAF 59/376 reads (16%) | called by mutect2, pindel, varscan2
- ARPP21 | c.2345C>A p.P782Q | Missense Mutation (SNP) | VAF 98/660 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- BNC2 | c.1244C>A p.T415N | Missense Mutation (SNP) | VAF 68/409 reads (17%) | SIFT tolerated (0.32); PolyPhen benign (0); called by muse, mutect2, varscan2
- BRCA2 | c.8100_8101del p.S2701* | Frame Shift Del (DEL) | VAF 24/216 reads (11%) | called by pindel, varscan2
- C12orf50 | c.239T>C p.L80S | Missense Mutation (SNP) | VAF 83/265 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CACNA1E | c.3136A>G p.I1046V | Missense Mutation (SNP) | VAF 22/168 reads (13%) | SIFT tolerated (0.74); PolyPhen benign (0); called by muse, mutect2, varscan2
- CCDC141 | c.3154C>G p.H1052D | Missense Mutation (SNP) | VAF 63/427 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.786); called by muse, mutect2, varscan2
- CCDC150 | c.901G>A p.D301N | Missense Mutation (SNP) | VAF 21/185 reads (11%) | SIFT tolerated (0.37); PolyPhen probably damaging (0.919); called by muse, mutect2, varscan2
- CCDC170 | c.1666C>A p.H556N | Missense Mutation (SNP) | VAF 105/634 reads (17%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- CD5L | c.788G>T p.G263V | Missense Mutation (SNP) | VAF 62/454 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- CDK16 | c.440G>A p.R147H | Missense Mutation (SNP) | VAF 48/165 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.308); called by muse, mutect2, varscan2
- CIB3 | c.143C>A p.T48N | Missense Mutation (SNP) | VAF 50/323 reads (15%) | SIFT tolerated (0.87); PolyPhen benign (0); called by muse, mutect2, varscan2
- CIP2A | c.2634G>T p.L878F | Missense Mutation (SNP) | VAF 71/288 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CLCA2 | c.2239G>C p.G747R | Missense Mutation (SNP) | VAF 84/920 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2
- CLEC16A | c.1040C>A p.A347D | Missense Mutation (SNP) | VAF 32/442 reads (7%) | SIFT tolerated (0.5); PolyPhen benign (0.009); called by muse, mutect2
- COL5A2 | c.202G>T p.A68S | Missense Mutation (SNP) | VAF 63/724 reads (9%) | SIFT tolerated (0.3); PolyPhen benign (0.138); called by muse, mutect2
- CPA3 | c.421T>A p.S141T | Missense Mutation (SNP) | VAF 38/156 reads (24%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.541); called by muse, mutect2, varscan2
- CSMD3 | c.9388G>T p.G3130C (on ENST00000297405 / NM_001363185.1; = p.G2961C on NM_052900.3) | Missense Mutation (SNP) | VAF 22/211 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2
- CYTIP | c.761C>A p.T254K | Missense Mutation (SNP) | VAF 85/616 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- DCDC2 | c.470T>C p.L157P | Missense Mutation (SNP) | VAF 53/366 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- DNAJC5B | c.166G>T p.A56S | Missense Mutation (SNP) | VAF 18/356 reads (5%) | SIFT tolerated (0.08); PolyPhen benign (0.009); called by muse, mutect2
- DPPA2 | c.560C>G p.A187G | Missense Mutation (SNP) | VAF 154/715 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- DYNC2H1 | c.10762-2A>G p.X3588_splice | Splice Site (SNP) | VAF 46/265 reads (17%) | called by muse, mutect2, varscan2
- DYSF | c.2270C>G p.A757G | Missense Mutation (SNP) | VAF 101/718 reads (14%) | SIFT tolerated (0.13); PolyPhen benign (0.142); called by muse, mutect2, varscan2
- EPPIN | c.103A>C p.K35Q | Missense Mutation (SNP) | VAF 48/368 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.326); called by muse, mutect2, varscan2
- EXTL1 | c.327G>T p.E109D | Missense Mutation (SNP) | VAF 36/190 reads (19%) | SIFT tolerated (0.08); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- FAM135B | c.3785G>A p.S1262N | Missense Mutation (SNP) | VAF 60/444 reads (14%) | SIFT tolerated (0.67); PolyPhen benign (0.418); called by muse, varscan2
- FBXL4 | c.284C>T p.A95V | Missense Mutation (SNP) | VAF 44/320 reads (14%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- FSIP2 | c.12211G>A p.D4071N | Missense Mutation (SNP) | VAF 22/213 reads (10%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.737); called by muse, mutect2
- GDF6 | c.302T>G p.I101S | Missense Mutation (SNP) | VAF 95/503 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- GJA8 | c.1183G>T p.G395W | Missense Mutation (SNP) | VAF 91/728 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.514); called by muse, mutect2, varscan2
- GLI2 | c.1183-4C>T | Splice Region (SNP) | VAF 107/640 reads (17%) | called by muse, mutect2, varscan2
- GOLGA8M | c.1699C>A p.L567I | Missense Mutation (SNP) | VAF 90/1199 reads (8%) | SIFT deleterious (0.05); PolyPhen benign (0.203); called by muse, mutect2
- GPRC6A | c.1044T>A p.S348R | Missense Mutation (SNP) | VAF 42/220 reads (19%) | SIFT tolerated (0.42); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- HAO2 | c.622C>A p.L208I | Missense Mutation (SNP) | VAF 98/806 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- HRC | c.437C>T p.A146V | Missense Mutation (SNP) | VAF 101/586 reads (17%) | SIFT tolerated (0.05); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- HSPA8 | c.1444G>T p.A482S | Missense Mutation (SNP) | VAF 59/477 reads (12%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.19); called by muse, mutect2, varscan2
- HUS1B | c.767A>T p.D256V | Missense Mutation (SNP) | VAF 102/551 reads (19%) | SIFT tolerated (0.18); PolyPhen benign (0.129); called by muse, mutect2, varscan2
- IFIH1 | c.1743G>T p.W581C | Missense Mutation (SNP) | VAF 26/284 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.969); called by muse, mutect2
- IGHG1 | c.340+1G>A p.X114_splice | Splice Site (SNP) | VAF 59/496 reads (12%) | called by muse, mutect2, varscan2
- JPH2 | c.440T>C p.V147A | Missense Mutation (SNP) | VAF 78/712 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.705); called by muse, mutect2, varscan2
- KALRN | c.5766G>C p.Q1922H (on ENST00000360013 / NM_001024660.4; = p.Q225H on NM_007064.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 66/450 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.399); called by muse, mutect2, varscan2
- KCNQ3 | c.1739C>T p.P580L | Missense Mutation (SNP) | VAF 141/856 reads (16%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- LCT | c.4315C>A p.L1439M | Missense Mutation (SNP) | VAF 136/867 reads (16%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.79); called by muse, mutect2, varscan2
- LNX1 | c.723del p.N242Tfs*25 (on ENST00000263925 / NM_001126328.3; = p.N146Tfs*25 on NM_032622.2) | Frame Shift Del (DEL) | VAF 64/514 reads (12%) | called by mutect2, pindel, varscan2
- MAGEA6 | c.151G>T p.G51W | Missense Mutation (SNP) | VAF 30/151 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.949); called by muse, mutect2, varscan2
- MAGEA8 | c.608G>T p.G203V | Missense Mutation (SNP) | VAF 39/167 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- MAP3K11 | c.1639C>T p.Q547* | Nonsense Mutation (SNP) | VAF 10/120 reads (8%) | called by muse, mutect2
- MECOM | c.2422C>T p.H808Y (on ENST00000468789 / NM_001105078.4; = p.H996Y on NM_004991.4) | Missense Mutation (SNP) | VAF 37/233 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.846); called by muse, mutect2, varscan2
- MS4A4A | c.361G>T p.A121S | Missense Mutation (SNP) | VAF 55/453 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- MSH6 | c.2435T>C p.L812P | Missense Mutation (SNP) | VAF 56/284 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MUC5B | c.10496C>T p.T3499I | Missense Mutation (SNP) | VAF 92/934 reads (10%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.452); called by muse, mutect2
- NALCN | c.821A>T p.Y274F | Missense Mutation (SNP) | VAF 31/240 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- NCEH1 | c.505G>T p.E169* (on ENST00000538775; = p.E129* on NM_020792.6 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 18/224 reads (8%) | called by muse, mutect2
- NCEH1 | c.504T>A p.D168E (on ENST00000538775; = p.D128E on NM_020792.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 18/226 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.863); called by muse, mutect2
- NIN | c.5496G>T p.Q1832H (on ENST00000382041 / NM_182946.1; = p.Q1119H on NM_016350.4) | Missense Mutation (SNP) | VAF 57/360 reads (16%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- NTHL1 | c.442G>T p.A148S (on ENST00000219066; = p.A140S on NM_002528.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 39/241 reads (16%) | SIFT tolerated (0.57); PolyPhen benign (0.304); called by muse, mutect2, varscan2
- OR52H1 | c.575C>G p.A192G (on ENST00000322653; = p.A198G on NM_001005289.1) | Missense Mutation (SNP) | VAF 58/435 reads (13%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- OR5L1 | c.801T>G p.S267R | Missense Mutation (SNP) | VAF 46/505 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.046); called by muse, mutect2
- RAD17 | c.837G>T p.E279D (on ENST00000380774 / NM_133339.2; = p.E268D on NM_002873.1) | Missense Mutation (SNP) | VAF 42/220 reads (19%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.479); called by muse, mutect2, varscan2
- RALGAPA2 | c.550+1G>A p.X184_splice | Splice Site (SNP) | VAF 50/201 reads (25%) | called by muse, varscan2
- REG1A | c.404G>T p.G135V | Missense Mutation (SNP) | VAF 27/365 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2
- ROBO2 | c.15T>A p.H5Q | Missense Mutation (SNP) | VAF 20/87 reads (23%) | SIFT tolerated, low confidence (0.43); called by muse, mutect2, varscan2
- SCN3B | c.488A>T p.Y163F | Missense Mutation (SNP) | VAF 113/916 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.495); called by muse, mutect2, varscan2
- SDK1 | c.343A>T p.I115F | Missense Mutation (SNP) | VAF 82/711 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.541); called by muse, mutect2, varscan2
- SH3TC1 | c.3935A>G p.N1312S | Missense Mutation (SNP) | VAF 107/778 reads (14%) | SIFT tolerated (0.1); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- SMG8 | c.166A>T p.T56S | Missense Mutation (SNP) | VAF 24/110 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.096); called by muse, mutect2, varscan2
- SPEF2 | c.1433T>C p.V478A | Missense Mutation (SNP) | VAF 54/537 reads (10%) | SIFT tolerated (0.07); PolyPhen benign (0.01); called by muse, varscan2
- TEFM | c.606A>C p.L202F | Missense Mutation (SNP) | VAF 58/391 reads (15%) | SIFT tolerated (0.74); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- TPO | c.2459G>T p.G820V | Missense Mutation (SNP) | VAF 118/971 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.609); called by muse, mutect2, varscan2
- TRAPPC2B | c.152A>T p.E51V | Missense Mutation (SNP) | VAF 227/1142 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); called by muse, mutect2, varscan2
- TRAV26-2 | c.90C>G p.N30K | Missense Mutation (SNP) | VAF 32/224 reads (14%) | SIFT tolerated (0.27); PolyPhen benign (0.058); called by mutect2, varscan2
- TRHR | c.500A>G p.N167S | Missense Mutation (SNP) | VAF 30/708 reads (4%) | SIFT tolerated (0.56); PolyPhen benign (0.017); called by muse, mutect2
- TSPEAR | c.428C>T p.T143I | Missense Mutation (SNP) | VAF 65/537 reads (12%) | SIFT tolerated (0.07); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- UBQLN3 | c.374C>A p.P125Q | Missense Mutation (SNP) | VAF 26/231 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.192); called by muse, mutect2, varscan2
- UBQLN3 | c.373C>A p.P125T | Missense Mutation (SNP) | VAF 27/233 reads (12%) | SIFT tolerated (0.25); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- VCAN | c.4319C>T p.S1440F | Missense Mutation (SNP) | VAF 79/462 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.768); called by muse, mutect2, varscan2
- VPS8 | c.379dup p.S127Ffs*24 | Frame Shift Ins (INS) | VAF 32/301 reads (11%) | called by mutect2, pindel, varscan2
- ZFHX4 | c.6200T>A p.V2067D | Missense Mutation (SNP) | VAF 10/203 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.474); called by muse, mutect2
- ZNF138 | c.592G>A p.E198K (on ENST00000307355 / NM_001367572.1; = p.E172K on NM_006524.4) | Missense Mutation (SNP) | VAF 40/247 reads (16%) | SIFT tolerated (0.22); PolyPhen benign (0.075); called by muse, mutect2, varscan2
- ZNF469 | c.10097C>G p.P3366R (on ENST00000437464; = p.P3394R on NM_001367624.2) | Missense Mutation (SNP) | VAF 41/183 reads (22%) | SIFT tolerated (0.84); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- ZNF831 | c.3467C>A p.S1156* | Nonsense Mutation (SNP) | VAF 18/194 reads (9%) | called by muse, mutect2
- ABCA3 | c.174G>T p.P58= | Silent (SNP) | VAF 123/988 reads (12%) | catalogued as rs143814058, COSV100068360; called by muse, mutect2, varscan2
- APOBR | c.279G>T p.G93= | Silent (SNP) | VAF 11/72 reads (15%) | called by muse, mutect2, varscan2
- ARNTL2 | c.981T>C p.I327= | Silent (SNP) | VAF 94/360 reads (26%) | called by muse, mutect2, varscan2
- CAPN2 | c.741C>T p.A247= | Silent (SNP) | VAF 75/649 reads (12%) | called by muse, mutect2, varscan2
- CASS4 | c.546C>A p.G182= | Silent (SNP) | VAF 31/254 reads (12%) | called by muse, mutect2, varscan2
- CDH18 | c.1125G>T p.G375= | Silent (SNP) | VAF 34/593 reads (6%) | catalogued as COSV99932076; called by muse, mutect2
- CHPF2 | c.1263C>T p.R421= | Silent (SNP) | VAF 20/410 reads (5%) | catalogued as rs1462567918; called by muse, mutect2
- CIB3 | c.144C>A p.T48= | Silent (SNP) | VAF 51/328 reads (16%) | called by muse, mutect2, varscan2
- COBL | c.381G>T p.L127= | Silent (SNP) | VAF 58/373 reads (16%) | catalogued as COSV99473521; called by muse, mutect2, varscan2
- CPN2 | c.1446C>G p.T482= | Silent (SNP) | VAF 43/289 reads (15%) | called by muse, mutect2, varscan2
- CRTC3 | c.606T>C p.H202= | Silent (SNP) | VAF 44/516 reads (9%) | catalogued as rs777608717; called by muse, mutect2
- FAT3 | c.6213G>A p.R2071= | Silent (SNP) | VAF 58/442 reads (13%) | catalogued as COSV53166659; called by muse, mutect2, varscan2
- FBN1 | c.6774T>C p.C2258= | Silent (SNP) | VAF 75/809 reads (9%) | catalogued as CD158312; called by muse, mutect2
- FLNC | c.7206C>T p.A2402= | Silent (SNP) | VAF 33/530 reads (6%) | called by muse, mutect2
- FREM1 | c.3402G>A p.E1134= | Silent (SNP) | VAF 25/227 reads (11%) | catalogued as COSV101084013, COSV66517863; called by muse, mutect2, varscan2
- GASK1A | c.993C>T p.S331= | Silent (SNP) | VAF 29/241 reads (12%) | called by muse, mutect2, varscan2
- GDPD2 | c.1527C>T p.F509= | Silent (SNP) | VAF 63/249 reads (25%) | called by muse, mutect2, varscan2
- GJB2 | c.498G>T p.L166= | Silent (SNP) | VAF 48/432 reads (11%) | called by muse, mutect2, varscan2
- GPR139 | c.363G>A p.P121= | Silent (SNP) | VAF 62/448 reads (14%) | catalogued as rs748486913; called by muse, mutect2, varscan2
- HTR2C | c.930G>C p.S310= | Silent (SNP) | VAF 105/396 reads (27%) | catalogued as rs1183790629; called by muse, varscan2
- IMPG2 | c.1104G>T p.L368= | Silent (SNP) | VAF 32/252 reads (13%) | catalogued as COSV51981712; called by muse, mutect2, varscan2
- KIF2B | c.391C>T p.L131= | Silent (SNP) | VAF 53/405 reads (13%) | catalogued as rs1229083918, COSV52129831, COSV52133600; called by muse, mutect2, varscan2
- MADD | c.1701C>T p.H567= | Silent (SNP) | VAF 60/379 reads (16%) | called by muse, mutect2, varscan2
- MS4A4E | c.951C>T p.P317= | Silent (SNP) | VAF 13/88 reads (15%) | called by muse, mutect2, varscan2
- MYH8 | c.366C>T p.G122= | Silent (SNP) | VAF 180/1103 reads (16%) | called by muse, mutect2, varscan2
- NCKAP5L | c.120G>A p.L40= | Silent (SNP) | VAF 82/262 reads (31%) | catalogued as rs999037824; called by muse, mutect2, varscan2
- NMS | c.399C>A p.P133= | Silent (SNP) | VAF 77/700 reads (11%) | called by muse, mutect2, varscan2
- NPAP1 | c.1071C>G p.L357= | Silent (SNP) | VAF 30/204 reads (15%) | catalogued as COSV61505364; called by muse, mutect2, varscan2
- OR2AJ1 | c.855C>G p.L285= | Silent (SNP) | VAF 50/421 reads (12%) | called by muse, mutect2, varscan2
- OR2T2 | c.900A>T p.A300= | Silent (SNP) | VAF 85/1360 reads (6%) | called by muse, mutect2
- OSBP2 | c.681C>T p.T227= | Silent (SNP) | VAF 14/401 reads (3%) | called by muse, mutect2
- PCDHA13 | c.2268G>T p.P756= | Silent (SNP) | VAF 69/360 reads (19%) | catalogued as COSV56546067; called by muse, mutect2, varscan2
- PHACTR2 | c.1749G>C p.T583= | Silent (SNP) | VAF 52/418 reads (12%) | called by muse, varscan2
- PLCH2 | c.4248C>A p.L1416= | Silent (SNP) | VAF 75/302 reads (25%) | called by muse, mutect2, varscan2
- PRKCG | c.1380C>T p.Y460= | Silent (SNP) | VAF 186/1036 reads (18%) | catalogued as rs762961166, COSV54723632, COSV54727512; called by muse, mutect2, varscan2
- PTX4 | c.858C>T p.L286= (on ENST00000447419 / NM_001328608.2; = p.L281= on NM_001013658.1) | Silent (SNP) | VAF 12/118 reads (10%) | called by muse, mutect2
- RGS21 | c.51A>T p.T17= | Silent (SNP) | VAF 50/615 reads (8%) | called by muse, mutect2
- SERPINA11 | c.1113C>T p.A371= | Silent (SNP) | VAF 19/118 reads (16%) | catalogued as rs776751744; called by muse, mutect2, varscan2
- SH3KBP1 | c.933G>A p.L311= | Silent (SNP) | VAF 73/234 reads (31%) | called by muse, mutect2, varscan2
- SLC28A1 | c.978C>T p.I326= | Silent (SNP) | VAF 118/898 reads (13%) | catalogued as rs762020765; called by muse, mutect2, varscan2
- SLC39A6 | c.1656C>T p.D552= | Silent (SNP) | VAF 75/433 reads (17%) | catalogued as rs368857974; called by muse, mutect2, varscan2
- SLITRK3 | c.1251C>T p.S417= | Silent (SNP) | VAF 61/472 reads (13%) | catalogued as COSV99579938; called by muse, varscan2
- SMAD9 | c.552T>A p.P184= | Silent (SNP) | VAF 131/1060 reads (12%) | called by muse, mutect2, varscan2
- TBX6 | c.1170G>T p.P390= | Silent (SNP) | VAF 22/137 reads (16%) | called by muse, mutect2, varscan2
- ARMC5 | chr16:31458412 G>C | 5'Flank (SNP) | VAF 51/348 reads (15%) | called by muse, mutect2, varscan2
- BTN2A1 | c.*167C>G | 3'UTR (SNP) | VAF 62/502 reads (12%) | called by muse, mutect2, varscan2
- C6 | c.*4A>G | 3'UTR (SNP) | VAF 36/366 reads (10%) | called by muse, varscan2
- CCDC40 | c.2619+51del | Intron (DEL) | VAF 93/562 reads (17%) | called by mutect2, pindel, varscan2
- COPS9 | c.64-10C>T | Intron (SNP) | VAF 52/292 reads (18%) | catalogued as rs1319606783; called by muse, mutect2, varscan2
- EYS | c.1767-6693C>G | Intron (SNP) | VAF 98/1566 reads (6%) | called by muse, mutect2
- FAM24B | chr10:122883819 C>A | 5'Flank (SNP) | VAF 47/243 reads (19%) | called by muse, mutect2, varscan2
- FGFR4 | c.1058-109T>C | Intron (SNP) | VAF 64/326 reads (20%) | called by muse, mutect2, varscan2
- GOLT1B | c.118-424A>G | Intron (SNP) | VAF 19/207 reads (9%) | called by muse, mutect2, varscan2
- GORAB | c.*756G>C | 3'UTR (SNP) | VAF 21/118 reads (18%) | called by muse, mutect2, varscan2
- GTF3C2 | c.-25+599G>A | Intron (SNP) | VAF 57/412 reads (14%) | called by muse, mutect2, varscan2
- GUSB | c.913-42A>G | Intron (SNP) | VAF 62/386 reads (16%) | called by muse, mutect2, varscan2
- HCN1 | c.-12C>T | 5'UTR (SNP) | VAF 76/327 reads (23%) | called by muse, mutect2, varscan2
- KRT8P11 | n.503G>T | RNA (SNP) | VAF 91/505 reads (18%) | called by muse, mutect2, varscan2
- KRT8P11 | n.504G>T | RNA (SNP) | VAF 94/507 reads (19%) | called by muse, mutect2, varscan2
- MALRD1 | c.4688-228G>A | Intron (SNP) | VAF 37/264 reads (14%) | catalogued as rs186329120; called by muse, varscan2
- NAMPTP1 | n.23C>A | RNA (SNP) | VAF 71/410 reads (17%) | called by muse, mutect2, varscan2
- OR2M1P | n.525C>A | RNA (SNP) | VAF 46/498 reads (9%) | called by muse, mutect2
- PARGP1 | n.553A>G | RNA (SNP) | VAF 171/902 reads (19%) | called by muse, mutect2, varscan2
- PIK3C2B | c.934-1609C>T | Intron (SNP) | VAF 22/270 reads (8%) | called by muse, mutect2
- POLM | c.372+345T>G | Intron (SNP) | VAF 56/385 reads (15%) | called by muse, mutect2, varscan2
- RBMXL2 | c.-6G>T | 5'UTR (SNP) | VAF 79/541 reads (15%) | catalogued as rs1300767156; called by muse, mutect2, varscan2
- SMIM19 | c.135-243G>A | Intron (SNP) | VAF 79/528 reads (15%) | catalogued as rs1464282711; called by muse, mutect2, varscan2
- SRD5A1 | c.294-6959A>T | Intron (SNP) | VAF 39/483 reads (8%) | catalogued as COSV57015580; called by muse, mutect2
- TPCN1 | c.-125-1473T>G | Intron (SNP) | VAF 91/304 reads (30%) | called by muse, mutect2, varscan2
- TPP1 | c.1267-45G>T | Intron (SNP) | VAF 176/1052 reads (17%) | called by muse, mutect2, varscan2
- VAPB | c.*4304T>A | 3'UTR (SNP) | VAF 329/1461 reads (23%) | called by muse, mutect2, varscan2
- VWA1 | c.-14G>T | 5'UTR (SNP) | VAF 20/86 reads (23%) | called by muse, varscan2
- ZNF99 | c.*3155C>T | 3'UTR (SNP) | VAF 34/159 reads (21%) | catalogued as rs568660344; called by muse, mutect2, varscan2
